Gene-level copy-number profile of tumor specimen TCGA-AA-3860-01A from TCGA case TCGA-AA-3860, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 53.2 years (19,449 days).
Specimen TCGA-AA-3860-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.15de0c3c-2fe1-4ce9-a490-67ade7a6d14a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AA-3860-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/093157e4-10e8-47a4-8fa6-65aa7ef19a00

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 16; copy number 1: 19,953; copy number 2: 37,323; copy number 3: 1,287; copy number 4: 898; copy number 6: 34; copy number 7: 40; copy number 8: 234; copy number 9: 12; copy number 12: 21.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-AA-3860-01): tumor purity 0.79, ploidy 1.72, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 16 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:150,579,089–150,721,478, 3 genes: AC110813.1, MAB21L2, ZBTB8OSP1.
- chr16:6,037,210–7,126,639, 10 genes: AC009135.2, AC009135.1, AC006112.1, AC007223.1, AC007012.2, AC007012.1, RNU7-99P, RNU6-457P, RNU6-328P, AC022206.1.
- chr20:14,933,843–15,022,958, 3 genes: AL138808.1, RNU6-1159P, RNU6-115P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 341 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:63,193,072–71,652,611, 86 genes, copy number 6–9 (broad region; genes not listed).
- chr13:18,467,172–28,495,145, 255 genes, copy number 8–12 (within-gene range 2–12) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 19,042. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
